Somatic mutation profile of tumor specimen TCGA-A3-A8OX-01A (aliquot TCGA-A3-A8OX-01A-11D-A36X-10) from TCGA case TCGA-A3-A8OX, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.7 years (23,998 days).
Specimen TCGA-A3-A8OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a7f80d5-1c8d-491e-a9b2-c12a0dc09d50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A8OX-10A (Blood Derived Normal), aliquot TCGA-A3-A8OX-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11e78073-cd2e-4d27-9c26-d89ee5928372

The open-access MAF lists 43 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 13, Nonsense Mutation 4, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.240T>A p.S80R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM941367, COSV56542846, COSV56543658; called by muse, mutect2
- AC023055.1 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100278404; called by muse, mutect2
- ALPK3 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99360134; called by muse, mutect2
- ANK2 | c.8657T>C p.L2886S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.005); catalogued as rs745359722, COSV99999380; called by muse, mutect2, varscan2
- CCDC93 | c.1775A>T p.N592I | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100098311; called by muse, mutect2
- CFAP54 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV61571481; called by muse, mutect2
- CFAP61 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs750210901, COSV55629755, COSV55645473; called by muse, mutect2
- CLEC12B | c.678C>T p.S226= | Splice Region (SNP) | VAF 9/155 reads (6%) | catalogued as COSV58863653; called by muse, mutect2
- CLHC1 | c.1661T>A p.L554* | Nonsense Mutation (SNP) | VAF 12/129 reads (9%) | catalogued as COSV101284832; called by muse, mutect2
- DNAH2 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101208968; called by muse, mutect2, varscan2
- F8 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100811230; called by muse, mutect2
- FMN2 | c.3875C>G p.P1292R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100142373; called by muse, mutect2
- FRY | c.2888C>A p.S963* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100968773, COSV104430891; called by muse, mutect2, varscan2
- HAMP | c.22T>G p.W8G | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99723037; called by muse, mutect2
- INTS8 | c.2300C>G p.P767R | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100569109; called by muse, mutect2
- KANK4 | c.953T>G p.V318G | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1252814215, COSV100586976; called by muse, mutect2
- MAEA | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.151); catalogued as COSV99295110; called by muse, mutect2
- MAP3K4 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100815006; called by muse, mutect2
- NIPSNAP3B | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101044414; called by muse, mutect2
- PDE5A | c.1133A>C p.D378A | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV99308225; called by muse, mutect2
- POLE | c.2645A>G p.N882S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs539312991, COSV100265227, COSV57678820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF3 | c.1318C>G p.L440V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV100254452; called by muse, mutect2
- SLC20A1 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753087768, COSV99733858; called by muse, mutect2
- TRIM23 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773959470, COSV99139853; called by muse, mutect2
- UBA3 | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100734582; called by muse, mutect2
- VHL | c.393C>G p.N131K | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as CM042502, CX073799, COSV56548229, COSV56549993; called by muse, mutect2
- VSTM1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs529993082, COSV100618654; called by muse, mutect2
- ZNF354A | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100234300; called by muse, mutect2, varscan2
- OR51E1 | c.866_867del p.L289Qfs*44 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel
- CDNF | c.540G>A p.A180= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs762047925, COSV101012357; called by muse, mutect2
- DENND1B | c.1782T>C p.F594= | Silent (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- GREB1 | c.1221G>A p.L407= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV99302143; called by muse, mutect2
- IFT172 | c.1893G>A p.L631= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as rs774534899, COSV99561695; ClinVar: likely benign; called by muse, mutect2
- MRPL24 | c.126C>A p.R42= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- OR5P3 | c.726C>T p.T242= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs752427289, COSV60429811; called by muse, mutect2
- PTPRB | c.2994C>G p.V998= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV99715595; called by muse, mutect2
- SMCO1 | c.456C>T p.H152= | Silent (SNP) | VAF 12/175 reads (7%) | catalogued as rs764420028, COSV100534816; called by muse, mutect2
- THSD1 | c.2166A>G p.L722= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as COSV51632735; called by muse, mutect2
- TRIM28 | c.1977A>T p.V659= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV99448636; called by muse, mutect2
- ZNF302 | c.1173C>A p.R391= (on ENST00000627982; = p.R312= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV101416428; called by muse, mutect2
- ZNF683 | c.1119T>C p.T373= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100853646; called by muse, mutect2
- ZNF835 | c.672C>T p.C224= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as rs964046739, COSV101606249, COSV73379304; called by muse, mutect2
- OR2W5 | n.348C>T | RNA (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
